Gene-level copy-number profile of tumor specimen TCGA-19-1389-02A from TCGA case TCGA-19-1389, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.1 years (18,659 days).
Specimen TCGA-19-1389-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.e0aee51e-d8b2-44f1-a19d-a12bfb5ff0c4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-1389-10C (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/f23c999d-eaf1-4aac-82fa-702b418e80d4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,401; copy number 1: 8,799; copy number 2: 46,044; copy number 3: 3,019; copy number 4: 7; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:124,397,303–124,868,326, 14 genes: OAT, NKX1-2, AL445237.1, LHPP, RPS10P18, AC068896.1, FAM53B, AL513190.1, FAM53B-AS1, EEF1AKMT2, Y_RNA, ABRAXAS2, Y_RNA, NPM1P31.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes, copy number 5: LCE3C, LCE3B.

Autosomal genes at a single copy (total copy number 1): 8,791. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
